MMRF case MMRF_1879 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d6e51aeb-799d-40b7-8a00-61220cf0f529

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Dead; Days to death: 323 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.0 years (25,572 days); ISS stage: I; Days to last known disease status: 323 days; Days to last follow up: 323 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 225 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 323.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 56.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 7.94 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 7.76 mmol/L.
- Day 85 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 6.62 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 4.1 µg/mL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 5.9 g/dL; Glucose 8.75 mmol/L.
- Day 169 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 5.85 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.5 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 5.78 mmol/L.
- Day 246 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 4.83 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 4.73 mmol/L.

Other clinical attributes
- Day -13: Weight: 73 kg; Height: 183 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1879_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1879_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
